Gene-level copy-number profile of tumor specimen TCGA-T3-A92M-01A from TCGA case TCGA-T3-A92M, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 52.7 years (19,247 days).
Specimen TCGA-T3-A92M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.10d6b09c-3107-48a3-a92c-94dbbed1a523.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-T3-A92M-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f42670f8-e87c-4b6f-a5ab-a5a566d0739c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 2,057; copy number 2: 20,400; copy number 3: 26,274; copy number 4: 5,620; copy number 5: 2,670; copy number 6: 999; copy number 7: 1,323; copy number 8: 145; copy number 9: 57; copy number 11: 19; copy number 12: 11; copy number 13: 16; copy number 14: 13; copy number 15: 47; copy number 16: 25; copy number 19: 3; copy number 20: 37; copy number 21: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-T3-A92M-01A-31D-A390-01): tumor purity 0.4, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 8 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr10:29,457,338–29,736,959, 4 genes (within-gene range 0–2): SVIL, MIR604, SNORD115, MIR938.
- chr12:12,611,827–12,829,975, 11 genes (within-gene range 0–3): CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1.
- chr13:20,403,666–21,061,586, 20 genes: CRYL1, MIR4499, AL590096.1, IFT88, SLC35E1P1, RNU2-7P, AL161772.1, IL17D, AL512652.2, EEF1AKMT1, RANP8, AL512652.1, XPO4, CNOT4P1, HNRNPA1P30, PPIAP27, RPSAP54, LATS2, LATS2-AS1, RNU4-9P.
- chr13:31,846,713–32,299,125, 1 gene (within-gene range 0–2): FRY.
- chr13:31,960,325–32,031,639, 3 genes: AC002525.1, Metazoa_SRP, FRY-AS1.
- chr17:72,627,231–72,644,490, 2 genes: RPL32P33, AC080037.2.
- chr17:72,663,823–72,664,152, 1 gene: RN7SKP180.
- chr18:24,364,787–25,352,190, 21 genes: AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,717 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:124,723,788–198,222,513, 1,353 genes, copy number 7–9 (broad region; genes not listed).
- chr4:66,431,092–74,589,481, 170 genes, copy number 8–16 (broad region; genes not listed).
- chr6:11,607,552–12,406,781, 13 genes, copy number 8: AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2, HIVEP1, EDN1, SUMO2P12, RN7SKP293.
- chr6:65,302,522–66,728,904, 6 genes, copy number 8: AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P.
- chr8:36,378,069–40,402,010, 95 genes, copy number 9–20 (within-gene range 2–20) (broad region; genes not listed).
- chr11:69,641,156–71,252,577, 37 genes, copy number 13–21 (within-gene range 1–21): CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr12:73,115,957–73,208,317, 3 genes, copy number 19 (within-gene range 4–19): AC090503.2, LINC02444, AC090503.1.
- chr12:74,248,637–74,728,851, 8 genes, copy number 15: AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3.
- chr19:23,762,944–28,125,430, 32 genes, copy number 7–12 (within-gene range 2–12): AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1, ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.

Autosomal genes at a single copy (total copy number 1): 1,507. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
